Surgical pathology report (de-identified scan), TCGA case TCGA-85-8072, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-8072-01A (Primary Tumor).

[page 1 of 2]
TCGA Pathology Reports

		OpenClinica ID	Gross Description	Microscopic Description	Diagnosis Details	Comments

[page 2 of 2]
Formatted Path
Report

LUNG TISSUE CHECKLIST

Specimen type: Lobectomy
Tumor site: Lung
Tumor size: 1.5 x 1.5 x 1
cm
Histologic type: Squamous
cell carcinoma
Histologic grade: Poorly
differentiated
Tumor extent: Not
specified
Other tumor nodules: Not
specified
Lymph nodes: Not
specified
Lymphatic invasion: Not
specified
Venous invasion: Not
specified
Margins: Not specified
Evidence of neo-adjuvant
treatment: Not specified
Additional pathologic
findings: Not specified
Comments: None

Laterality

Left-upper

Excision date

Source: NCI Genomic Data Commons file 0e8a751b-3c01-492d-9ed9-272e23f849ce (TCGA-85-8072.31100521-D4EA-4E5F-98CE-21010CCCE324.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).